Somatic mutation profile of tumor specimen TCGA-CR-6467-01A (aliquot TCGA-CR-6467-01A-11D-1870-08) from TCGA case TCGA-CR-6467, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 59.4 years (21,689 days).
Specimen TCGA-CR-6467-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2072677-b776-4e91-8617-07f65cdc0ebc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-6467-10A (Blood Derived Normal), aliquot TCGA-CR-6467-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/acf966bb-f172-442d-836a-a18c1b7e6f17

The open-access MAF lists 46 somatic variants for this specimen: 31 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 25, Silent 15, Nonsense Mutation 3, Frame Shift Del 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIF1A | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs797045655, COSV57486594; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.3179C>T p.T1060M | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as rs768978840, COSV101316274; called by muse, mutect2, varscan2
- AKAP3 | c.2294C>T p.T765M | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs199800327, COSV57417467; called by muse, mutect2, varscan2
- CCM2L | c.1318G>A p.E440K (on ENST00000452892 / NM_001365692.1; = p.G418= on NM_080625.4) | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV99395013, COSV99395352; called by muse, mutect2, varscan2
- CKAP5 | c.2568G>C p.E856D | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100371166; called by muse, mutect2, varscan2
- DCLRE1C | c.536G>A p.R179Q (on ENST00000378278 / NM_001350965.2; = p.R64Q on NM_022487.4) | Missense Mutation (SNP) | VAF 37/189 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs150854849, COSV100739935; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DHX58 | c.1936C>T p.R646W | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as rs892878434, COSV104381120, COSV99288406; called by muse, mutect2, varscan2
- DNAH2 | c.3371G>A p.W1124* | Nonsense Mutation (SNP) | VAF 29/112 reads (26%) | catalogued as COSV101209509; called by muse, mutect2, varscan2
- DPP9 | c.2054G>T p.R685L (on ENST00000598800; = p.R714L on NM_139159.5) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99506357; called by muse, varscan2
- EEPD1 | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99632757; called by muse, mutect2, varscan2
- FSCB | c.2159C>T p.P720L | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.023); catalogued as COSV100469645; called by muse, mutect2, varscan2
- GLOD4 | c.68A>G p.Y23C | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs879191124, COSV100022704; called by muse, mutect2, varscan2
- GPC5 | c.835C>T p.R279* | Nonsense Mutation (SNP) | VAF 23/52 reads (44%) | catalogued as rs184809659, COSV65610669; called by muse, mutect2, varscan2
- KLHL17 | c.1138G>T p.A380S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.989); catalogued as rs1222084303, COSV100498119; called by muse, mutect2
- LSS | c.1523G>A p.G508E | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100710991; called by muse, mutect2, varscan2
- MC3R | c.49G>A p.G17S | Missense Mutation (SNP) | VAF 59/224 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV54763038; called by muse, mutect2, varscan2
- OTOGL | c.4392G>A p.M1464I (on ENST00000547103; = p.M1455I on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100087648; called by muse, mutect2, varscan2
- PCDH8 | c.2330G>A p.R777H | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV58811324; called by muse, mutect2, varscan2
- PDE7A | c.190C>T p.R64C (on ENST00000401827 / NM_001242318.3; = p.R38C on NM_002603.4) | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs780918402, COSV101052704; called by muse, mutect2, varscan2
- RPL4 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 28/39 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100328846; called by muse, mutect2, varscan2
- RPP25L | c.416C>G p.P139R | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.831); catalogued as COSV99426988; called by muse, mutect2, varscan2
- SLC24A2 | c.1078+1G>A p.X360_splice | Splice Site (SNP) | VAF 51/223 reads (23%) | catalogued as COSV99647114; called by muse, mutect2, varscan2
- SYNE1 | c.14186C>T p.A4729V (on ENST00000367255 / NM_182961.4; = p.A4658V on NM_033071.3) | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs749275993, COSV54909248; called by muse, mutect2, varscan2
- TACC2 | c.8063G>A p.R2688Q (on ENST00000334433; = p.R766Q on NM_006997.4) | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs760546620, COSV53286135; called by muse, mutect2, varscan2
- TCERG1 | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 85/162 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.281); catalogued as rs760840255, COSV99695118; called by muse, mutect2, varscan2
- TTLL2 | c.985dup p.S329Ffs*5 | Frame Shift Ins (INS) | VAF 70/202 reads (35%) | catalogued as rs770551644; called by mutect2, varscan2
- WDTC1 | c.1867G>A p.D623N (on ENST00000319394 / NM_001276252.2; = p.D622N on NM_015023.5) | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.028); catalogued as COSV100089311; called by muse, mutect2, varscan2
- XYLT1 | c.2774C>G p.T925R | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.478); catalogued as COSV54486134, COSV99762823; called by muse, mutect2, varscan2
- ZSCAN5B | c.569C>G p.A190G | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100748507; called by muse, mutect2
- HLA-A | c.460_479del p.L154Gfs*16 | Frame Shift Del (DEL) | VAF 18/35 reads (51%) | called by mutect2, pindel, varscan2
- RIMBP3 | c.2764C>T p.Q922* | Nonsense Mutation (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- APBA3 | c.1200G>C p.R400= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV99516360; called by muse, mutect2, varscan2
- ASH2L | c.1446G>A p.Q482= | Silent (SNP) | VAF 120/684 reads (18%) | catalogued as COSV99167019; called by muse, mutect2, varscan2
- ATP5F1A | c.1347C>T p.F449= | Silent (SNP) | VAF 56/106 reads (53%) | catalogued as rs141613719; called by muse, mutect2, varscan2
- ILK | c.657G>A p.V219= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as COSV100196551; called by muse, mutect2, varscan2
- ITGB4 | c.5283C>T p.S1761= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV99564471; called by muse, mutect2, varscan2
- KPRP | c.171C>T p.C57= | Silent (SNP) | VAF 31/114 reads (27%) | catalogued as COSV64221271; called by muse, mutect2, varscan2
- MAPKAP1 | c.663G>A p.P221= | Silent (SNP) | VAF 29/153 reads (19%) | catalogued as rs374415747, COSV56372601; called by muse, mutect2, varscan2
- NAA11 | c.21G>A p.Q7= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV99727501; called by muse, mutect2, varscan2
- NDNF | c.1440C>T p.I480= | Silent (SNP) | VAF 24/99 reads (24%) | catalogued as COSV101113223; called by muse, mutect2, varscan2
- OBSL1 | c.846G>A p.E282= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs758731589, COSV99217251; called by muse, mutect2, varscan2
- PPP1R10 | c.1341G>A p.A447= | Silent (SNP) | VAF 115/163 reads (71%) | catalogued as rs760305884, COSV100919923; called by muse, mutect2, varscan2
- PRRC2B | c.6450C>T p.P2150= | Silent (SNP) | VAF 16/117 reads (14%) | catalogued as rs750885962; called by muse, mutect2, varscan2
- TBC1D9 | c.1719T>A p.A573= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as COSV101464383; called by muse, mutect2, varscan2
- XPO7 | c.2154T>A p.T718= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV99381782; called by muse, mutect2, varscan2
- ZHX2 | c.2355C>T p.N785= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs746899768, COSV58711951; called by muse, mutect2, varscan2
